Somatic mutation profile of tumor specimen TCGA-OR-A5LE-01A (aliquot TCGA-OR-A5LE-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LE, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 14.7 years (5,383 days).
Specimen TCGA-OR-A5LE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea3dbd5f-5f24-4baa-81fc-53c9ab459da1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LE-10A (Blood Derived Normal), aliquot TCGA-OR-A5LE-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6245a9f-ca42-4cd8-99b3-0058cc699371

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV57387118; called by muse, mutect2, varscan2
- RANBP17 | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs748335843, COSV66651949; called by muse, mutect2
- SLK | c.3194C>T p.T1065I | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV59828588; called by muse, mutect2, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 22/31 reads (71%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- ATP8A2 | c.3109A>G p.T1037A | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRCA2 | c.2201_2202insCTTCTTCTT p.V733_L734insFFF | In Frame Ins (INS) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- CLCN1 | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); called by muse, mutect2
- CRB1 | c.3450T>G p.H1150Q | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by mutect2, varscan2
- CREB3L1 | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DOP1A | c.1074C>G p.I358M | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ISL1 | c.486del p.I163Sfs*26 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | called by mutect2, varscan2
- KIFBP | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PAPSS2 | c.731_732del p.L244Pfs*7 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by pindel, varscan2
- PDX1 | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PTPN2 | c.326T>A p.V109D | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SHROOM4 | c.3790T>A p.S1264T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEF | c.870G>C p.K290N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- DOT1L | c.462C>T p.T154= | Silent (SNP) | VAF 100/213 reads (47%) | catalogued as rs756501559; called by muse, mutect2, varscan2
- KCNJ3 | c.531C>T p.I177= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs866255726; called by muse, mutect2
- KLRG2 | c.771C>T p.Y257= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs1029951739; called by muse, mutect2, varscan2
